Surgical pathology report (de-identified scan), TCGA case TCGA-93-A4JN, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - St. Louis, specimen TCGA-93-A4JN-01A (Primary Tumor).

[page 1 of 4]
FINAL CORRECTED REPORT DATED

REPLACES ALL PREVIOUS VERSIONS.

Surgical Pathology Report

Final, Corrected

SURGICAL PATHOLOGY REPORT

*** CORRECTED REPORT ***

FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Cardiothoracic Surgery

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

LUNG, ****PARIETAL*** PLEURAL DEPOSIT, BIOPSY (INCLUDING FS1)

- ADENOCARCINOMA
- HYALINIZED GRANULOMAS
- SEE COMMENT

ICB-0-3

adenocarcinoma, acinar 8550/3

Path Site: lung, lingula c34.1

CACF : lung lower lobe c34.1

hw
10/2/12

LYMPH NODE, LEVEL 7, BIOPSY

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)
- HYALINIZED GRANULOMA

- NO FUNGAL FORMS OR MYCOBACTERIAL SPECIES IDENTIFIED ON GMS, AFB OR FITE STAINS

LYMPH NODE, LEVEL 11, BIOPSY

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)
- HYALINIZED GRANULOMA

LYMPH NODE, LEVEL 11, BIOPSY (INCLUDING FS2)

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)
- HYALINIZED GRANULOMA

LUNG, LINGULA, RESECTION (INCLUDING FS3)

- ADENOCARCINOMA (3.2 CM), INVASIVE AND POORLY DIFFERENTIATED
- TUMOR INVADERS INTO **** THE VISCERAL PLEURA (T2aN0M1a = STAGE IV)****
- ARTERIAL INVASION IDENTIFIED
- NON-TUMORAL LUNG WITH HYALINIZED GRANULOMAS
- SEE SYNOPSIS AND COMMENTS

By the signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material submitted in the diagnosis).

***Report Electronically Reviewed and Signed Out By

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to the frozen section area is 'lingula,' which consists of a pink-red wedge of lung, measuring 13 x 12.5 x 3 cm. Staple line removed and inked black. Sectioned to show a light brown-tan soft mass measuring 3.2 x 2.7 cm, located approximately 0.5 cm from the nearest inked margin. Portion frozen as FS3. Tissue taken for tuberculosis test. Rest for permanents," by

FS1: Pleural deposit, biopsy

- "Hyalinized granulomas, focal small basophilic nests, question tumorlets," by

FS2: Level 11 lymph nodes

- "Hyalinized granulomas, focally necrotizing, no evidence of malignancy," by

FS3: Lingula, excision

- "Adenocarcinoma, inked margin free of tumor," by

Microscopic Description and Comment:

Sections of the submitted "lingula" (part E) show an invasive, poorly differentiated adenocarcinoma (3.2 cm) which has an infiltrative and poorly circumscribed border, involving the visceral pleura (PL2). The tumor invades into but not through the visceral pleura (block E7). All surgical resection margins are free of tumor. Of note, multiple intra-arterial invasions with tumor cells colonizing the endothelial wall are also seen. A provisional primary tumor staging is provided as T2a based on the staging information from the "lingula" specimen.

Additional sections of the specimen "pleural deposit" (part A) show focal small basophilic nests of tumor cells with some features of neuroendocrine differentiation. Small amount of mature adipose tissue is also present. At deeper level, some of these areas also showed tubular and acinar architecture. These tumor cells are positive for TTF-1 and are negative for synaptophysin and chromogranin, confirming their malignant nature.

****Per discussion with _____ we understand that the submitted "pleural deposit" (part A) was acquired from distant parietal pleural site (M1a). This report is amended to include this information and to upstage the lesion to STAGE IV.****

Numerous granulomas are seen (part B, part C, part D, part E). GMS, FITE, AFB are performed on the lymph node specimen acquired from level 7 (part B) and the results are negative.

also reviewed select sections and concurs with final diagnosis.

History:

The patient is _____ who presents with a pre-operative diagnosis of lung mass. Pre-operative biopsy show no evidence of malignancy in multiple lymph nodes

Operative procedure: Video-assisted lingulectomy.

Specimen(s) Received:

- A: PLEURAL DEPOSIT
- B: LYMPH NODE, LEVEL 7
- C: LYMPH NODE, LEVEL 11
- D: LYMPH NODE, LEVEL 11
- E: LINGULA

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Gross Description:

The specimens are received in five formalin-filled containers, each labeled with the patient's name. The first container is additionally labeled "pleural deposit; FS1." It contains a green tissue cassette labeled "FS1," which holds multiple minute brown-tan frozen section tissue remnants, measuring 0.5 x 0.3 x 0.1 cm in aggregate. Wrapped. Labeled A1 (FS1). Jar 0.

The second container is labeled "level 7 lymph nodes." It contains a pink-tan lymph node candidate, measuring 2 x 1 x 1 cm in greatest dimension. Bisected to show no grossly identifiable lesion. Labeled B1. Jar 0.

The third container is labeled "level 11 lymph node." It contains one single pink-brown lymph node candidate, measuring 0.9 x 0.8 x 0.6 cm. Bisected. Labeled C1. Jar 0.

The fourth container is labeled "level 11 lymph node; FS2." It contains a green tissue cassette labeled "FS2," which holds two pieces of brown-pink frozen section tissue remnants, measuring 1 x 1.2 x 0.3 cm and 1 x 1.2 x 0.3 cm each. Labeled D1 (FS2). Jar 0.

The fifth container is labeled "lingula; FS3." It contains a green tissue cassette labeled "FS3," which holds a 1.8 x 1.2 x 0.2 cm pink-tan frozen section tissue remnant. Labeled E1 (FS3). Also present within the container is a previously inked and sectioned lingula lobectomy specimen, weighing 78.5 g, and measuring 13 x 12.5 x 3 cm. A staple line is present at the site of resection. The staple line is removed and its underlying parenchymal resection margin is inked black. Sectioned to show a 3.2 x 2.7 x 2.5 cm tumor mass, which is located approximately 0.5 cm from the nearest inked parenchymal resection margin (sampled in E3) and is located 1.2 from the bronchial resection margin. The pleural surface overlying the tumor shows puckering that measures 0.5 cm in the greatest dimension. The pleural surface in this area is inked blue. The uninvolved area of lung is further sectioned to show brown-tan, spongy, unremarkable parenchyma. Upon further inspection, a 0.2 cm white-yellow, pearly lesion is present at the periphery of the pleural surface (sampled in E8). Labeled E2 - bronchial and vascular resection margin; E3 - tumor in relation to the nearest inked parenchymal resection margin; E4 - tumor in relation to the pleural puckering; E5 - additional tumor with pleural puckering; E6 - additional tumor with black inked parenchymal resection margin; E7 - more tumor with pleural puckering; E8 - 0.4 cm pearly pleural nodule; E9 - grossly uninvolved lung. Jar 2.

Upper lobe
nos

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

The provided tumor staging also includes the information acquired from the patients prior biopsy specimen

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is adenocarcinoma, acinar (usual) type

HISTOLOGIC GRADE (G)

The grade of the tumor is poorly differentiated (G3)

TUMOR SIZE

The maximum dimension of the tumor is 3.2 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is absent (L0)

VENOUS INVASION

Venous invasion by tumor is absent (V0)

ARTERIAL INVASION

Arterial invasion by tumor is present

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

PLEURAL INVOLVEMENT

Pleural involvement is present; tumor invades through visceral pleura, without involvement of parietal pleura (PL2)

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

NON-NEOPLASTIC TISSUE

The non-neoplastic lung tissue shows granulomatous inflammation

PRIMARY TUMOR (T)

Tumor > 3 cm but ≤ 7 cm or tumor with any of the following features (T2 tumors with these features are classified as T2a if ≤ 5 cm) (T2)

Invades visceral pleura (PL1 or PL2)

Tumor > 3 cm but ≤ 5 cm in greatest dimension (T2a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically, no examination for ITC (pN0)

DISTANT METASTASIS (M)

Separate tumor nodules in contralateral lobe; tumor with pleural nodules or malignant pleural or pericardial effusion (M1a)

STAGE GROUPING

The overall international stage is T2a/N0/M1a (Stage IV)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Corrections

Corrected:

Previous Signout Date:

Comment: This case was corrected to change the synoptic report.

Corrected:

Previous Signout Date:

Comment: This case was corrected to change the synoptic report.

Surgical Pathology report is available

Source: NCI Genomic Data Commons file 0d97da20-01e8-4bd3-bb56-1a7e01aa70cf (TCGA-93-A4JN.BA9DB454-6107-4F98-8646-89129230D602.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).